Somatic mutation profile of tumor specimen TCGA-13-1506-01A (aliquot TCGA-13-1506-01A-01W-0549-09) from TCGA case TCGA-13-1506, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 45.8 years (16,734 days).
Specimen TCGA-13-1506-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 843064a1-9df8-4f62-8d0f-15777bad0aa6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1506-10A (Blood Derived Normal), aliquot TCGA-13-1506-10A-01W-0550-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80e2ec5a-d251-4f18-acb2-fbca579101df

The open-access MAF lists 27 somatic variants for this specimen: 23 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Intron 2, Silent 2, Splice Site 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.7526G>T p.S2509I | Missense Mutation (SNP) | VAF 98/351 reads (28%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.756); catalogued as COSV71289081; called by muse, mutect2, varscan2
- ALPK3 | c.2533G>C p.G845R | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); catalogued as COSV51934219; called by muse, mutect2, varscan2
- ANKRD27 | c.2438C>T p.P813L | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60132183; called by muse, mutect2, varscan2
- BCL2L15 | c.193A>C p.N65H | Missense Mutation (SNP) | VAF 142/295 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV63643037; called by muse, mutect2, varscan2
- BTBD2 | c.454G>A p.G152R | Missense Mutation (SNP) | VAF 21/22 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762340181, COSV55309084; called by muse, mutect2, varscan2
- BTN1A1 | c.316C>A p.R106S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0.006); catalogued as COSV55067338, COSV55067939; called by muse, mutect2, varscan2
- CD99L2 | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1557418987, COSV60935281; called by muse, mutect2, varscan2
- CTIF | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); catalogued as rs202032754, COSV56484793; called by muse, mutect2, varscan2
- FAM160A2 | c.1772G>A p.R591Q (on ENST00000449352 / NM_001098794.2; = p.R605Q on NM_032127.4) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.294); catalogued as rs770178853, COSV56409427, COSV99792511; called by muse, mutect2, varscan2
- GLIS3 | c.1918C>G p.P640A | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV60929805; called by muse, mutect2, varscan2
- IGSF3 | c.2062A>G p.T688A (on ENST00000369486 / NM_001007237.3; = p.T708A on NM_001542.4) | Missense Mutation (SNP) | VAF 107/421 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV59591680; called by muse, mutect2, varscan2
- LHX8 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV53957111; called by muse, mutect2, varscan2
- LRIG2 | c.1092-1G>A p.X364_splice | Splice Site (SNP) | VAF 41/260 reads (16%) | catalogued as rs780891386, COSV63162354; called by muse, mutect2, varscan2
- OVCH1 | c.2890G>A p.D964N | Missense Mutation (SNP) | VAF 78/710 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.036); catalogued as COSV58963510; called by muse, mutect2, varscan2
- PIEZO2 | c.6949C>T p.R2317* | Nonsense Mutation (SNP) | VAF 145/164 reads (88%) | catalogued as rs1329879893, COSV53290118, COSV99555074; called by muse, mutect2, varscan2
- PPP1R3F | c.1936A>T p.M646L | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV50018592; called by muse, mutect2, varscan2
- RASSF9 | c.743A>T p.D248V | Missense Mutation (SNP) | VAF 78/323 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV63434022, COSV63435213; called by muse, mutect2, varscan2
- SSH1 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV58456851; called by muse, mutect2, varscan2
- TFAP2D | c.52G>A p.G18R | Missense Mutation (SNP) | VAF 73/247 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50419352; called by muse, mutect2, varscan2
- TIAM2 | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV59706057; called by muse, mutect2
- TP53 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 420/448 reads (94%) | SIFT tolerated (0.23); PolyPhen benign (0.159); catalogued as CM120852, COSV52811974, COSV52991347; called by muse, varscan2
- GPR179 | c.5023C>T p.L1675F (on ENST00000621958; = p.L1674F on NM_001004334.4) | Missense Mutation (SNP) | VAF 80/192 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- TP53 | c.195_196insCCCAGAAT p.M66Pfs*60 | Frame Shift Ins (INS) | VAF 6/69 reads (9%) | called by pindel, varscan2*
- ATP4B | c.504C>G p.P168= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV58929094; called by muse, mutect2, varscan2
- TMEM132B | c.1839C>T p.I613= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as rs370664891, COSV54755187; called by muse, mutect2, varscan2
- ATP2B4 | c.3309+5777C>G | Intron (SNP) | VAF 60/622 reads (10%) | catalogued as COSV100397242; called by muse, mutect2
- SYTL2 | c.1459+2597G>A | Intron (SNP) | VAF 76/298 reads (26%) | catalogued as rs1443889638, COSV60358918; called by muse, mutect2, varscan2
